Gene-level copy-number profile of tumor specimen TCGA-CX-7082-01A from TCGA case TCGA-CX-7082, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 82.6 years (30,174 days).
Specimen TCGA-CX-7082-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a3e9465b-c53b-4aa4-b2ac-fe3fa9a76c47.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CX-7082-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/61f7061d-1acd-497e-ab21-0ac3b353e024

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 156; copy number 1: 1,180; copy number 2: 13,825; copy number 4: 38,028; copy number 5: 2,527; copy number 6: 3,044; copy number 7: 134; copy number 8: 64; copy number 9: 30; copy number 10: 154; copy number 11: 179; copy number 12: 101; copy number 13: 176; copy number 14: 63; copy number 16: 90; copy number 17: 48; copy number 19: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CX-7082-01): tumor purity 0.59, ploidy 3.66, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 156 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:178,094,104–178,484,147, 2 genes (within-gene range 0–4): RASAL2, AL160281.1.
- chr21:10,328,411–21,797,415, 154 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 854 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,794,017–121,580,524, 47 genes, copy number 14: REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr3:160,755,602–193,782,758, 497 genes, copy number 9–19 (within-gene range 6–19) (broad region; genes not listed).
- chr3:196,739,857–196,832,647, 1 gene, copy number 12 (within-gene range 7–12): PAK2.
- chr3:196,784,980–198,222,513, 47 genes, copy number 12: RNU6-42P, SENP5, AC016949.1, NCBP2, NCBP2-AS1, NCBP2AS2, PIGZ, AC011322.1, RPSAP69, MELTF, MELTF-AS1, DLG1, MIR4797, DLG1-AS1, AL121981.1, AC128709.2, AC128709.1, AC128709.3, LINC02012, BDH1, AC132008.2, AC132008.1, AC024560.2, AC024560.3, AC024560.4, AC024560.1, AC024560.5, RUBCN, MIR922, FYTTD1, AC055764.2, LRCH3, AC055764.1, AC144530.1, IQCG, RNU6-858P, RPL35A, LMLN, RNU6-621P, AC135893.1, LMLN-AS1, ANKRD18DP, RNU6-821P, FRG2FP, TUBB8P8, AC073135.1, FAM157A.
- chr4:77,157,207–77,433,388, 1 gene, copy number 9 (within-gene range 4–9): CCNG2.
- chr4:77,311,397–77,351,235, 2 genes, copy number 9: AC008638.2, AC008638.1.
- chr6:46,129,989–46,146,688, 1 gene, copy number 13: ENPP4.
- chr7:96,306,810–96,709,891, 5 genes, copy number 9 (within-gene range 6–9): AC084368.1, RNU6-532P, RNU6-364P, RNU7-188P, SEM1.
- chr10:85,378,327–85,432,775, 1 gene, copy number 11 (within-gene range 4–11): LINC02647.
- chr11:69,147,228–71,252,577, 48 genes, copy number 17 (within-gene range 12–17): AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.
- chr13:26,905,362–28,778,937, 50 genes, copy number 10–13: FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P.
- chr14:35,756,327–38,371,338, 51 genes, copy number 13: AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1, CLEC14A, AL355835.1.
- chr14:52,267,698–53,157,528, 22 genes, copy number 10: PTGDR, AL365475.1, PTGER2, TXNDC16, GPR137C, ERO1A, AL133453.1, PSMC6, STYX, GNPNAT1, AL139317.3, AL139317.5, AL139317.1, AL139317.2, FERMT2, AL139317.4, AL352979.4, AL352979.1, AL352979.3, DDHD1, AL352979.2, AL356020.1.
- chr14:53,364,146–53,392,048, 1 gene, copy number 10: AL365295.2.
- chr19:27,638,483–27,646,483, 2 genes, copy number 10: ERVK-28, AC112702.1.
- chr20:5,126,879–10,636,829, 78 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
